Somatic mutation profile of cancer-model specimen HCM-BROD-0417-C71-85A (3D Neurosphere, passage 10; aliquot HCM-BROD-0417-C71-85A-01D-A82H-36), derived from the primary tumor of HCMI case HCM-BROD-0417-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 50.0 years (18,275 days).
Specimen HCM-BROD-0417-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1884a493-97f1-48b3-9c15-01c67e042b0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0417-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0417-C71-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3b1d6c0-14a6-402e-8b62-6b437afa6433

The open-access MAF lists 105 somatic variants for this specimen: 81 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 21, Nonsense Mutation 7, Intron 3, Frame Shift Del 2, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 333/629 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AKR7A2 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 236/363 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs1458311650; called by muse, mutect2, varscan2
- ANO4 | c.1450C>A p.P484T (on ENST00000392977 / NM_001286615.2; = p.P449T on NM_178826.4) | Missense Mutation (SNP) | VAF 64/806 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV100151220; called by muse, mutect2
- ARHGEF17 | c.1851del p.G618Efs*9 | Frame Shift Del (DEL) | VAF 244/570 reads (43%) | catalogued as rs764619467; called by mutect2, pindel, varscan2
- ASMT | c.273C>G p.S91R | Missense Mutation (SNP) | VAF 97/626 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as COSV101172480; called by muse, mutect2, varscan2
- CDC42BPA | c.1692G>C p.E564D | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs759486214; called by muse, mutect2, varscan2
- DDX60L | c.4505C>G p.P1502R | Missense Mutation (SNP) | VAF 106/164 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99487591; called by muse, mutect2, varscan2
- FLNA | c.4909G>A p.V1637M | Missense Mutation (SNP) | VAF 418/910 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as rs1333867692, COSV61053313; called by muse, mutect2, varscan2
- FNDC1 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 149/334 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1031735872, COSV51949316; called by muse, mutect2, varscan2
- HERC1 | c.13528C>T p.R4510* | Nonsense Mutation (SNP) | VAF 25/404 reads (6%) | catalogued as COSV71247677; called by muse, mutect2
- IGLV3-19 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 189/189 reads (100%) | catalogued as rs1264631654; called by muse, mutect2, varscan2
- IP6K3 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 101/625 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs140887508; called by muse, mutect2, varscan2
- KRT39 | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV62916950; called by muse, mutect2, varscan2
- KSR2 | c.1125C>A p.F375L | Missense Mutation (SNP) | VAF 219/1067 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as COSV56669188; called by muse, mutect2, varscan2
- LZTR1 | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 421/421 reads (100%) | catalogued as rs768530578; called by muse, mutect2, varscan2
- MYO18B | c.5395C>T p.R1799* | Nonsense Mutation (SNP) | VAF 32/189 reads (17%) | catalogued as rs916672722; called by muse, mutect2, varscan2
- NEK9 | c.1685A>G p.N562S | Missense Mutation (SNP) | VAF 13/457 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1298074833; called by muse, mutect2
- NF1 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1555604925; ClinVar: uncertain significance; called by muse, mutect2
- NYX | c.214A>C p.N72H | Missense Mutation (SNP) | VAF 540/1053 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM158331; called by muse, mutect2, varscan2
- OR10H5 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 169/339 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs149384614; called by muse, mutect2, varscan2
- OR10R2 | c.45C>G p.F15L | Missense Mutation (SNP) | VAF 197/414 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100936828, COSV63769543; called by muse, mutect2, varscan2
- OR5D16 | c.443T>A p.V148D | Missense Mutation (SNP) | VAF 237/389 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV65721821; called by muse, mutect2
- PTPN14 | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 137/311 reads (44%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.978); catalogued as rs1336851908, COSV65281181; called by muse, varscan2
- RNF43 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 44/686 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.009); catalogued as rs760426158; ClinVar: uncertain significance; called by muse, mutect2
- RP1L1 | c.4356G>T p.E1452D | Missense Mutation (SNP) | VAF 46/669 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs991629743, COSV66760727; called by muse, mutect2
- RYR1 | c.9452A>G p.Q3151R | Missense Mutation (SNP) | VAF 90/1946 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV62094057; called by muse, mutect2
- SAMD9L | c.4406C>A p.S1469Y | Missense Mutation (SNP) | VAF 19/636 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV59080579; called by muse, mutect2
- SLC2A9 | c.145A>G p.R49G | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1444873235; called by muse, mutect2, varscan2
- TP53 | c.965del p.P322Hfs*23 | Frame Shift Del (DEL) | VAF 183/533 reads (34%) | catalogued as COSV52729459, COSV52826955; called by mutect2, pindel, varscan2
- TPP1 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 238/326 reads (73%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs149986601; called by muse, mutect2, varscan2
- TRIM14 | c.1199G>A p.G400D | Missense Mutation (SNP) | VAF 443/722 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216598011; called by muse, mutect2, varscan2
- TTLL3 | c.2348G>C p.R783T | Missense Mutation (SNP) | VAF 106/273 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.049); catalogued as COSV59615343; called by muse, mutect2, varscan2
- USH1C | c.902G>A p.R301Q | Missense Mutation (SNP) | VAF 317/345 reads (92%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as rs556221893, COSV99040689; called by muse, mutect2, varscan2
- VCAN | c.6004G>A p.E2002K | Missense Mutation (SNP) | VAF 32/633 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV54098476, COSV54112314; called by muse, mutect2
- VGLL3 | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 22/584 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67353908; called by muse, mutect2
- WIZ | c.4200G>T p.K1400N (on ENST00000673675 / NM_001371589.1; = p.K305N on NM_021241.3) | Missense Mutation (SNP) | VAF 183/370 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV54609077; called by muse, mutect2, varscan2
- ZNF546 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 105/618 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV61257330; called by muse, mutect2, varscan2
- ZNF729 | c.2609A>G p.H870R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs543424536; called by muse, mutect2, varscan2
- ACTL6A | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ADGRD2 | c.1095G>T p.L365F | Missense Mutation (SNP) | VAF 60/396 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALG9 | c.620G>A p.W207* | Nonsense Mutation (SNP) | VAF 158/347 reads (46%) | called by muse, mutect2, varscan2
- ATP6AP1 | c.1075T>A p.S359T | Missense Mutation (SNP) | VAF 155/889 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- AURKB | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 39/781 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, mutect2
- BTBD8 | c.3382G>A p.V1128I (on ENST00000636805 / NM_001376131.1; = p.V615I on NM_015237.4) | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CRISP3 | c.398T>A p.M133K (on ENST00000371159 / NM_001368123.1; = p.M115K on NM_006061.4) | Missense Mutation (SNP) | VAF 161/294 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- DCSTAMP | c.852G>A p.W284* | Nonsense Mutation (SNP) | VAF 188/434 reads (43%) | called by muse, mutect2, varscan2
- DNAH6 | c.9314A>G p.D3105G | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DST | c.3962C>G p.P1321R (on ENST00000361203 / NM_001374722.1; = p.P995R on NM_001723.6) | Missense Mutation (SNP) | VAF 108/235 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FAM47B | c.868A>G p.T290A | Missense Mutation (SNP) | VAF 84/488 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.743); called by mutect2, varscan2
- FRK | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 45/275 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GAA | c.1897C>A p.Q633K | Missense Mutation (SNP) | VAF 252/508 reads (50%) | SIFT tolerated (0.93); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- GBA2 | c.2210_2221dup p.N737_S740dup | In Frame Ins (INS) | VAF 200/568 reads (35%) | called by mutect2, varscan2
- H3Y1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 108/270 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HEATR1 | c.303G>C p.L101F | Missense Mutation (SNP) | VAF 20/418 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- HSPA4 | c.2356C>T p.P786S | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2
- KCNJ6 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 237/463 reads (51%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- KNG1 | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 29/226 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- LEP | c.300C>G p.D100E | Missense Mutation (SNP) | VAF 32/915 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- LOXHD1 | c.6484A>G p.T2162A (on ENST00000642948; = p.T2100A on NM_144612.7) | Missense Mutation (SNP) | VAF 139/456 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEC3 | c.41G>T p.S14I | Missense Mutation (SNP) | VAF 37/545 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- MAN2B2 | c.1157T>G p.F386C | Missense Mutation (SNP) | VAF 488/489 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MSS51 | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 145/145 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.37434G>A p.W12478* | Nonsense Mutation (SNP) | VAF 43/188 reads (23%) | called by muse, mutect2, varscan2
- OBSCN | c.773G>C p.S258T | Missense Mutation (SNP) | VAF 236/638 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OIP5 | c.466G>C p.A156P | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OTOG | c.2740A>C p.N914H | Missense Mutation (SNP) | VAF 47/404 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PHC2 | c.1003C>T p.L335F | Missense Mutation (SNP) | VAF 107/336 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- PLSCR1 | c.482C>A p.T161N | Missense Mutation (SNP) | VAF 170/363 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.444); called by mutect2, varscan2
- REST | c.2113C>A p.P705T | Missense Mutation (SNP) | VAF 122/1966 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.074); called by muse, mutect2
- RYR3 | c.1249T>G p.L417V | Missense Mutation (SNP) | VAF 24/389 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); called by muse, mutect2
- SIM1 | c.2161T>A p.L721I | Missense Mutation (SNP) | VAF 10/326 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- SLC22A2 | c.1241C>A p.A414E | Missense Mutation (SNP) | VAF 11/363 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SLC33A1 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 13/394 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC38A9 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.107); called by muse, mutect2
- TAT | c.656A>T p.N219I | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBX18 | c.302A>G p.E101G | Missense Mutation (SNP) | VAF 30/662 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- TMTC4 | c.162+1G>T p.X54_splice (on ENST00000376234 / NM_001350577.2; = p.X73_splice on NM_032813.5 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 145/145 reads (100%) | called by muse, mutect2, varscan2
- USP14 | c.1024A>G p.K342E | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- WNT2 | c.942C>A p.D314E | Missense Mutation (SNP) | VAF 266/885 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZBED1 | c.680C>G p.S227C | Missense Mutation (SNP) | VAF 622/1286 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ZNF546 | c.2233G>T p.G745C | Missense Mutation (SNP) | VAF 98/634 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACTL9 | c.996G>A p.A332= | Silent (SNP) | VAF 226/451 reads (50%) | catalogued as rs1369590050, COSV61006527; called by muse, mutect2, varscan2
- BIRC6 | c.3504T>G p.L1168= | Silent (SNP) | VAF 37/186 reads (20%) | called by muse, mutect2, varscan2
- CACNA1F | c.4632G>A p.E1544= | Silent (SNP) | VAF 28/609 reads (5%) | called by muse, mutect2
- CHST1 | c.333C>T p.A111= | Silent (SNP) | VAF 30/427 reads (7%) | catalogued as rs777954431, COSV57323037; called by muse, mutect2
- CIT | c.5790C>T p.N1930= | Silent (SNP) | VAF 46/1720 reads (3%) | catalogued as rs1301165297; called by muse, mutect2
- CLCNKA | c.774C>T p.S258= | Silent (SNP) | VAF 90/303 reads (30%) | catalogued as COSV58892992; called by muse, mutect2, varscan2
- DOCK2 | c.3510G>A p.S1170= | Silent (SNP) | VAF 19/246 reads (8%) | catalogued as rs747886113, COSV56967903, COSV56968121; called by muse, mutect2
- GPR119 | c.285G>C p.T95= | Silent (SNP) | VAF 354/803 reads (44%) | catalogued as COSV99358698; called by muse, mutect2, varscan2
- IQCH | c.1590C>T p.D530= | Silent (SNP) | VAF 77/279 reads (28%) | catalogued as rs763639911; called by muse, mutect2, varscan2
- IQSEC1 | c.1827G>A p.R609= | Silent (SNP) | VAF 149/430 reads (35%) | called by muse, mutect2, varscan2
- IVL | c.81C>A p.V27= | Silent (SNP) | VAF 89/778 reads (11%) | called by muse, mutect2, varscan2
- MUC4 | c.2373C>T p.A791= | Silent (SNP) | VAF 209/1216 reads (17%) | catalogued as rs773659222; called by muse, mutect2, varscan2
- NES | c.3135A>G p.S1045= | Silent (SNP) | VAF 38/1173 reads (3%) | called by muse, mutect2
- PCLO | c.3726C>A p.T1242= | Silent (SNP) | VAF 70/475 reads (15%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.2100A>G p.E700= | Silent (SNP) | VAF 17/257 reads (7%) | called by muse, mutect2
- PRRT4 | c.2613C>T p.A871= | Silent (SNP) | VAF 335/1133 reads (30%) | catalogued as rs1193445284; called by muse, mutect2, varscan2
- SCARA5 | c.630G>A p.A210= | Silent (SNP) | VAF 170/950 reads (18%) | catalogued as rs757727537; called by muse, mutect2, varscan2
- SHROOM2 | c.72G>C p.G24= | Silent (SNP) | VAF 33/1282 reads (3%) | called by muse, mutect2
- TCERG1L | c.1656A>T p.R552= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as COSV100894208; called by muse, mutect2, varscan2
- TMEM132D | c.2445G>A p.G815= | Silent (SNP) | VAF 232/502 reads (46%) | called by muse, mutect2, varscan2
- XCR1 | c.699C>A p.A233= | Silent (SNP) | VAF 111/577 reads (19%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+29615C>A | Intron (SNP) | VAF 40/224 reads (18%) | called by muse, mutect2, varscan2
- PAX1 | c.287-188C>T | Intron (SNP) | VAF 217/539 reads (40%) | called by muse, mutect2, varscan2
- SIRPB1 | c.77-9911C>A | Intron (SNP) | VAF 184/185 reads (99%) | called by muse, mutect2, varscan2
